Somatic mutation profile of tumor specimen C3L-03726-03 (aliquot CPT0225570006) from CPTAC case C3L-03726, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.4 years (28,285 days).
Specimen C3L-03726-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e294821-2655-42ef-b0ae-3784c483403c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03726-31 (Blood Derived Normal), aliquot CPT0226060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9df69e9-1854-4312-acfe-981f984edf76

The open-access MAF lists 263 somatic variants for this specimen: 180 protein-altering or splice-affecting, 55 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 55, Intron 13, Nonsense Mutation 9, Frame Shift Del 7, 3'UTR 6, 5'Flank 4, RNA 3, Splice Site 3, 5'UTR 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1802G>T p.R601L | Missense Mutation (SNP) | VAF 62/193 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV50266847; called by mutect2, varscan2
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 49/213 reads (23%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4091C>T p.A1364V | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as rs200857969, COSV52199286; called by muse, mutect2, varscan2
- ACKR1 | c.899C>A p.T300K | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1801482; called by muse, mutect2, varscan2
- ACTL6A | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs776228730; called by muse, mutect2, varscan2
- ADCY10 | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.141); catalogued as COSV63242826; called by muse, mutect2, varscan2
- ADGRB3 | c.1424G>T p.W475L | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.926); catalogued as COSV101002090; called by muse, mutect2, varscan2
- AFF3 | c.2101T>G p.S701A | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs745720488; called by muse, mutect2, varscan2
- ARHGAP36 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV52266997, COSV99358025; called by muse, mutect2, varscan2
- CFP | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV55949858, COSV55950678; called by muse, mutect2, varscan2
- COL11A2 | c.3233G>A p.G1078D (on ENST00000341947 / NM_080680.3; = p.G971D on NM_080679.2) | Missense Mutation (SNP) | VAF 123/739 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs561777123; called by muse, mutect2, varscan2
- COL4A2 | c.4841C>T p.A1614V | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs574412120; called by muse, mutect2, varscan2
- ERVV-2 | c.652G>T p.G218W | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1442437016; called by muse, mutect2, varscan2
- FAM71B | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs771658846, COSV100261957, COSV57229138; called by muse, varscan2
- FFAR3 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.387); catalogued as COSV100588148; called by mutect2, varscan2
- GPR68 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.967); catalogued as rs530459920; called by muse, mutect2, varscan2
- GRIP2 | c.378C>A p.D126E (on ENST00000619221; = p.D29E on NM_001080423.4) | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.08); catalogued as rs749908803, COSV56124794; called by muse, mutect2, varscan2
- HMGN5 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV63917720; called by muse, mutect2, varscan2
- KIF2B | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs796994270, COSV99276257; called by muse, mutect2, varscan2
- KIRREL3 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73104760; called by muse, mutect2, varscan2
- KLF5 | c.1069G>C p.V357L | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as rs1338061301; called by muse, mutect2, varscan2
- KLHL1 | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.91); catalogued as COSV100918132; called by muse, mutect2
- LEPROTL1 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs753060116; called by muse, mutect2, varscan2
- LRRC9 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs907997074; called by muse, mutect2, varscan2
- MC4R | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913562, CM003764, CM091291; called by muse, mutect2, varscan2
- MCF2L | c.1649G>T p.R550M (on ENST00000375608; = p.R518M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65049154; called by muse, mutect2
- MEGF8 | c.6889G>A p.G2297R (on ENST00000251268 / NM_001271938.2; = p.G2230R on NM_001410.3) | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1160168661, COSV52104759; called by muse, mutect2
- MTUS2 | c.2972G>T p.R991L | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs765544917, COSV70918277; called by muse, mutect2, varscan2
- MVK | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 52/186 reads (28%) | catalogued as CM010938; called by muse, mutect2, varscan2
- MYT1L | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV67729445; called by muse, mutect2, varscan2
- NAA15 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs376221285; called by muse, mutect2, varscan2
- NECTIN3 | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100162789; called by muse, mutect2, varscan2
- NMUR1 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59404602; called by muse, mutect2, varscan2
- NOL7 | c.425T>C p.L142S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.986); catalogued as rs759155299; called by muse, mutect2, varscan2
- NT5C1B | c.1189G>A p.V397I (on ENST00000359846 / NM_001199086.2; = p.V337I on NM_033253.4) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs144184703; called by muse, mutect2, varscan2
- P2RY8 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101183962; called by muse, mutect2, varscan2
- PCLO | c.6895del p.D2299Tfs*3 | Frame Shift Del (DEL) | VAF 28/117 reads (24%) | catalogued as COSV61627951; called by mutect2, pindel, varscan2
- PIGC | c.379A>C p.I127L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99278444; called by muse, mutect2, varscan2
- PKHD1 | c.11752G>T p.G3918W | Missense Mutation (SNP) | VAF 182/631 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV64396005; called by muse, mutect2, varscan2
- PPP1R3F | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV50018901; called by muse, mutect2
- PTH1R | c.1766G>T p.W589L | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.054); catalogued as COSV100480966; called by muse, mutect2, varscan2
- RGS12 | c.3476C>T p.A1159V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV58749019; called by muse, mutect2, varscan2
- RNFT2 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99064493; called by muse, mutect2, varscan2
- RTN1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1483373815; called by muse, mutect2, varscan2
- SALL1 | c.2041G>C p.D681H | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV51765666; called by muse, mutect2, varscan2
- SEMA3E | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs746153032; called by muse, varscan2
- SLC6A15 | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.072); catalogued as rs778180371, COSV57025857; called by muse, mutect2, varscan2
- SLC6A8 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557044167; called by muse, mutect2, varscan2
- SPATA31E1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV57790205; called by muse, mutect2, varscan2
- SPEG | c.7985T>A p.V2662E | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.131); catalogued as rs377713868, COSV100405061; called by muse, mutect2, varscan2
- STRC | c.4360G>T p.A1454S | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1239220467; called by muse, mutect2, varscan2
- TAS1R1 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV100062964; called by muse, mutect2, varscan2
- TH | c.1264G>A p.G422R (on ENST00000381178 / NM_199292.3; = p.G391R on NM_000360.4) | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1243080287; called by muse, mutect2
- TIAM1 | c.1810-1G>T p.X604_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | catalogued as COSV54539540; called by muse, mutect2, varscan2
- TMEM199 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201975015; called by muse, mutect2, varscan2
- TMPRSS11F | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs142296401; called by muse, mutect2, varscan2
- TRAPPC9 | c.1142A>T p.E381V | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV66896414; called by muse, mutect2, varscan2
- UBE2QL1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1372626798, COSV67715435, COSV67715637; called by muse, mutect2, varscan2
- WDR33 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59245859; called by muse, mutect2, varscan2
- ZFHX4 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 83/287 reads (29%) | catalogued as COSV50479944; called by muse, mutect2, varscan2
- ZFPM2 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); catalogued as COSV65875325; called by muse, mutect2, varscan2
- ABHD14B | c.436A>T p.N146Y | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ABT1 | c.322G>T p.G108* | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.3075G>T p.W1025C | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAP1 | c.493A>T p.R165* | Nonsense Mutation (SNP) | VAF 42/188 reads (22%) | called by muse, mutect2, varscan2
- ADGRA1 | c.491C>A p.P164Q | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AKAP9 | c.7416_7417del p.N2473* (on ENST00000359028; = p.N2449* on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | called by pindel, varscan2
- ALMS1 | c.7076T>C p.V2359A | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- AMER1 | c.2861G>T p.G954V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANKRD30B | c.984dup p.E329* | Frame Shift Ins (INS) | VAF 50/256 reads (20%) | called by pindel, varscan2
- ARMCX5-GPRASP2 | c.1435A>G p.R479G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ARR3 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP11C | c.3082G>T p.V1028L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- BCL6 | c.41A>T p.H14L | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BOD1L1 | c.5608G>C p.V1870L | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- BPNT2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C17orf97 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 146/546 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.43); called by muse, varscan2
- C6 | c.300+1G>T p.X100_splice | Splice Site (SNP) | VAF 36/238 reads (15%) | called by muse, mutect2, varscan2
- CABP5 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARD14 | c.2507C>A p.A836E | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CCDC174 | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.155); called by muse, mutect2
- CD82 | c.-102-4del | Splice Region (DEL) | VAF 52/189 reads (28%) | called by mutect2, pindel, varscan2
- CEACAM16 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CHD6 | c.4801A>G p.M1601V | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CHGA | c.1025G>A p.W342* | Nonsense Mutation (SNP) | VAF 55/237 reads (23%) | called by muse, mutect2, varscan2
- CLGN | c.438A>T p.Q146H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNN1 | c.121del p.V41* | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- COP1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- COQ9 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- CRIM1 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CYLC1 | c.1737C>A p.F579L | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DEFB133 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DENND4B | c.2180C>A p.P727Q | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); called by muse, mutect2
- DOCK2 | c.4841A>G p.E1614G | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DZIP1 | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EFR3B | c.1631A>G p.E544G | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- FAM71B | c.812T>A p.V271E | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, varscan2
- FCN2 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL2 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 156/412 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- FGF10 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 160/498 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- FUBP1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GALNTL6 | c.363del p.L122Cfs*42 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel
- GGA1 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- GLI3 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR45 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 55/406 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- GPR50 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- GREB1 | c.3624G>T p.Q1208H | Missense Mutation (SNP) | VAF 63/399 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- H2AZ2 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- HNRNPU | c.578T>A p.L193Q | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HYDIN | c.5420G>A p.S1807N | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- IGHV4-61 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- IL4 | c.460T>G p.*154Gext*3 | Nonstop Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- KRT6C | c.1666T>A p.S556T | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP13-3 | c.50del p.G17Vfs*77 | Frame Shift Del (DEL) | VAF 19/135 reads (14%) | called by mutect2, pindel
- LIPE | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- LMTK2 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LOXL1 | c.453C>A p.H151Q | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1 | c.4019A>T p.Q1340L | Missense Mutation (SNP) | VAF 76/338 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, varscan2
- LRRIQ3 | c.1194A>G p.I398M | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGIX | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MAP2 | c.2893G>C p.E965Q | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED27 | c.260A>T p.H87L | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MPEG1 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYBPC1 | c.278A>T p.K93I (on ENST00000550270 / NM_206820.2; = p.K118I on NM_002465.4) | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH6 | c.2689C>A p.Q897K | Missense Mutation (SNP) | VAF 55/428 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- NAA10 | c.122T>A p.L41H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NBR1 | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.017); called by muse, mutect2
- NDUFS1 | c.482A>G p.E161G | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NEB | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- NMUR1 | c.1089C>A p.F363L | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPM2 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- OCA2 | c.2042C>A p.T681N | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPA3 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 73/322 reads (23%) | called by muse, mutect2, varscan2
- OR2B6 | c.832T>A p.Y278N | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR2D2 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4C6 | c.803C>A p.A268E | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OR51A7 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5H6 | c.92C>G p.T31R (on ENST00000642105; = p.T15R on NM_001005479.2) | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- OXTR | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- PAK4 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PARP11 | c.386G>T p.W129L | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARP16 | c.95A>G p.Q32R | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH17 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGK1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PHLPP2 | c.3680A>G p.Q1227R | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PKHD1L1 | c.1688C>A p.A563D | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- PLD2 | c.1493A>C p.D498A | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNLIPRP1 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PRAMEF1 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 123/598 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PRAMEF1 | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 85/399 reads (21%) | called by muse, mutect2, varscan2
- PRDM11 | c.954G>T p.K318N (on ENST00000530656 / NM_001359633.1; = p.K284N on NM_001256695.1) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPN7 | c.683G>T p.C228F (on ENST00000495688; = p.C267F on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2
- PTPRQ | c.6599C>T p.P2200L (on ENST00000616559; = p.P2167L on NM_001145026.2) | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RNPC3 | c.236T>G p.I79R | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RTL4 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SIPA1L1 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- SKOR1 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SLC25A27 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 22/554 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2
- SLIT1 | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNAPC4 | c.648C>A p.H216Q | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2
- SORCS3 | c.2293C>A p.Q765K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STK11 | c.100_101del p.V34Hfs*128 | Frame Shift Del (DEL) | VAF 65/260 reads (25%) | called by mutect2, pindel, varscan2
- TAS2R60 | c.164del p.C55Lfs*8 | Frame Shift Del (DEL) | VAF 48/163 reads (29%) | called by mutect2, pindel, varscan2
- TEX13C | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TRPA1 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TUBGCP6 | c.1622A>T p.Y541F | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- U2AF2 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UBR4 | c.3166G>T p.D1056Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- USH2A | c.15230C>T p.P5077L | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP24 | c.5450A>G p.H1817R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USPL1 | c.2375G>A p.G792E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- XIRP2 | c.1011C>A p.N337K (on ENST00000628543; = p.N512K on NM_152381.6) | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- YME1L1 | c.1406+1G>C p.X469_splice (on ENST00000326799 / NM_139312.3; = p.X412_splice on NM_014263.4) | Splice Site (SNP) | VAF 10/307 reads (3%) | called by muse, mutect2
- ZBTB39 | c.2044G>A p.V682M | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ZFHX4 | c.2857C>T p.Q953* | Nonsense Mutation (SNP) | VAF 112/351 reads (32%) | called by muse, mutect2, varscan2
- ZIM2 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF219 | c.972C>A p.H324Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF616 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZNF677 | c.1379A>T p.K460I | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY1 | c.2511C>G p.L837= | Silent (SNP) | VAF 13/318 reads (4%) | catalogued as COSV52041320; called by muse, mutect2
- AMOT | c.1431G>A p.E477= (on ENST00000371959 / NM_001113490.1; = p.E68= on NM_133265.3) | Silent (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- ASIC2 | c.753G>A p.Q251= | Silent (SNP) | VAF 62/319 reads (19%) | catalogued as rs938589875; called by muse, mutect2, varscan2
- C6orf120 | c.522T>G p.V174= | Silent (SNP) | VAF 63/206 reads (31%) | called by muse, varscan2
- CCDC40 | c.2877T>C p.R959= | Silent (SNP) | VAF 72/325 reads (22%) | called by muse, mutect2, varscan2
- CD99L2 | c.171A>T p.P57= | Silent (SNP) | VAF 32/289 reads (11%) | catalogued as COSV60935312; called by muse, mutect2, varscan2
- CER1 | c.303T>C p.D101= | Silent (SNP) | VAF 90/323 reads (28%) | called by muse, mutect2, varscan2
- CKM | c.330C>A p.L110= | Silent (SNP) | VAF 52/366 reads (14%) | called by muse, mutect2, varscan2
- CTH | c.519A>T p.A173= | Silent (SNP) | VAF 73/315 reads (23%) | called by muse, mutect2, varscan2
- DCLRE1C | c.93G>T p.L31= | Silent (SNP) | VAF 57/329 reads (17%) | called by muse, mutect2, varscan2
- EVC2 | c.2175G>A p.Q725= | Silent (SNP) | VAF 98/425 reads (23%) | called by muse, mutect2, varscan2
- F2RL2 | c.981C>T p.N327= | Silent (SNP) | VAF 7/133 reads (5%) | called by muse, mutect2
- FRG2C | c.297A>G p.R99= | Silent (SNP) | VAF 48/376 reads (13%) | called by muse, mutect2, varscan2
- FYCO1 | c.873C>T p.L291= | Silent (SNP) | VAF 51/227 reads (22%) | called by muse, mutect2, varscan2
- HMX1 | c.246G>T p.R82= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- HSFX2 | c.171T>A p.P57= | Silent (SNP) | VAF 13/64 reads (20%) | called by mutect2, varscan2
- IL1R1 | c.37C>T p.L13= | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as rs777273469; called by muse, mutect2, varscan2
- KMT2D | c.14256C>T p.F4752= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs753311204; called by muse, mutect2, varscan2
- KRT35 | c.249G>T p.G83= | Silent (SNP) | VAF 83/336 reads (25%) | called by muse, mutect2, varscan2
- LRRC27 | c.471G>T p.V157= | Silent (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- LRRK1 | c.1074A>T p.T358= | Silent (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- MFSD2A | c.615G>T p.L205= (on ENST00000372809 / NM_001136493.3; = p.L192= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- MGAM2 | c.2358C>A p.S786= | Silent (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- NLRC3 | c.1881C>A p.G627= | Silent (SNP) | VAF 43/235 reads (18%) | catalogued as COSV100073665; called by muse, mutect2, varscan2
- OR6K2 | c.96C>A p.L32= | Silent (SNP) | VAF 77/238 reads (32%) | catalogued as COSV62743631; called by muse, mutect2, varscan2
- OR6M1 | c.876G>A p.E292= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- PAX7 | c.400C>A p.R134= | Silent (SNP) | VAF 32/122 reads (26%) | called by muse, mutect2, varscan2
- PIEZO1 | c.840C>T p.I280= | Silent (SNP) | VAF 64/281 reads (23%) | called by muse, mutect2, varscan2
- PLXNA1 | c.3522G>T p.R1174= | Silent (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- PLXNC1 | c.2460G>T p.T820= | Silent (SNP) | VAF 78/338 reads (23%) | catalogued as COSV51571199; called by muse, mutect2, varscan2
- POGK | c.582G>T p.R194= | Silent (SNP) | VAF 67/193 reads (35%) | called by muse, mutect2, varscan2
- POM121L2 | c.2427A>T p.P809= | Silent (SNP) | VAF 112/614 reads (18%) | called by muse, mutect2, varscan2
- PSG7 | c.951T>A p.G317= | Silent (SNP) | VAF 50/211 reads (24%) | called by muse, mutect2, varscan2
- PXDNL | c.1242T>A p.I414= | Silent (SNP) | VAF 56/167 reads (34%) | called by muse, mutect2, varscan2
- PYCARD | c.267G>T p.T89= | Silent (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.72G>T p.V24= | Silent (SNP) | VAF 108/345 reads (31%) | catalogued as rs1458804271; called by muse, mutect2, varscan2
- RBFOX2 | c.363C>G p.A121= (on ENST00000438146 / NM_001349995.2; = p.A51= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/562 reads (5%) | called by muse, mutect2
- RTL6 | c.190C>T p.L64= | Silent (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- SLC14A2 | c.2076G>A p.K692= | Silent (SNP) | VAF 57/150 reads (38%) | called by muse, mutect2, varscan2
- SLC4A10 | c.2274C>T p.S758= (on ENST00000446997 / NM_001354461.2; = p.S728= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- SOX5 | c.927A>T p.G309= | Silent (SNP) | VAF 54/265 reads (20%) | catalogued as rs752765179; called by muse, mutect2, varscan2
- SRCIN1 | c.1470C>A p.G490= (on ENST00000621492; = p.G456= on NM_025248.3) | Silent (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- SULF1 | c.681C>G p.P227= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs780642053; called by muse, mutect2, varscan2
- SYNGAP1 | c.1920C>G p.T640= | Silent (SNP) | VAF 103/646 reads (16%) | called by muse, varscan2
- TEDDM1 | c.585C>A p.I195= | Silent (SNP) | VAF 107/528 reads (20%) | catalogued as rs375818345; called by muse, mutect2, varscan2
- TLL2 | c.2577G>A p.T859= | Silent (SNP) | VAF 40/346 reads (12%) | catalogued as rs769603425; called by muse, mutect2, varscan2
- TLR4 | c.15G>T p.S5= | Silent (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- TYR | c.930A>C p.P310= | Silent (SNP) | VAF 88/451 reads (20%) | catalogued as rs373154185; called by muse, mutect2, varscan2
- VIT | c.1410C>A p.T470= (on ENST00000389975 / NM_001177969.1; = p.T485= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/190 reads (35%) | catalogued as COSV64896453; called by muse, mutect2, varscan2
- WNT3 | c.519G>T p.A173= | Silent (SNP) | VAF 65/282 reads (23%) | called by muse, mutect2, varscan2
- WNT7A | c.123C>A p.I41= | Silent (SNP) | VAF 66/268 reads (25%) | catalogued as COSV53202486; called by muse, mutect2, varscan2
- XPC | c.2193C>T p.G731= | Silent (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- ZAN | c.3009C>G p.P1003= | Silent (SNP) | VAF 46/190 reads (24%) | called by muse, mutect2, varscan2
- ZEB2 | c.2874A>G p.K958= | Silent (SNP) | VAF 41/336 reads (12%) | catalogued as rs559663433, COSV100356161; called by muse, mutect2, varscan2
- ZNF560 | c.69C>A p.T23= | Silent (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793821 G>A | 3'Flank (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
- ADAR | c.-935G>A | 5'UTR (SNP) | VAF 61/246 reads (25%) | catalogued as rs1297318149, COSV52719579; called by mutect2, varscan2
- AGAP1 | c.164-38254G>T | Intron (SNP) | VAF 33/74 reads (45%) | catalogued as rs780629881; called by muse, mutect2, varscan2
- CCAR2 | c.1041+134G>A | Intron (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- CHD2 | c.62+3638G>A | Intron (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- DISC1 | c.1981+36459A>G | Intron (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2, varscan2
- FNDC7 | c.*32G>A | 3'UTR (SNP) | VAF 39/172 reads (23%) | catalogued as rs1413827987; called by muse, mutect2, varscan2
- GMPR2 | c.*198G>A | 3'UTR (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- INTS8 | chr8:94823073 G>T | 5'Flank (SNP) | VAF 76/247 reads (31%) | called by muse, mutect2, varscan2
- LETMD1 | chr12:51048288 A>T | 5'Flank (SNP) | VAF 57/277 reads (21%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344688 C>A | 5'Flank (SNP) | VAF 72/519 reads (14%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344689 C>T | 5'Flank (SNP) | VAF 72/518 reads (14%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92590C>T | Intron (SNP) | VAF 52/206 reads (25%) | called by muse, mutect2, varscan2
- MS4A6E | c.147+517G>A | Intron (SNP) | VAF 11/98 reads (11%) | catalogued as COSV55727169; called by muse, mutect2, varscan2
- NSMAF | c.59+340T>A | Intron (SNP) | VAF 29/190 reads (15%) | called by muse, mutect2, varscan2
- OR2W5 | n.540T>C | RNA (SNP) | VAF 99/521 reads (19%) | called by muse, mutect2, varscan2
- PHKB | c.*42A>G | 3'UTR (SNP) | VAF 41/319 reads (13%) | catalogued as COSV100065331; called by muse, mutect2, varscan2
- PLEC | c.523+4938G>C | Intron (SNP) | VAF 10/116 reads (9%) | catalogued as rs1432511005; called by muse, mutect2
- RAB17 | c.*545G>T | 3'UTR (SNP) | VAF 59/178 reads (33%) | called by muse, mutect2, varscan2
- RBM38 | c.416+6606_416+6607insTTAG | Intron (INS) | VAF 26/253 reads (10%) | called by muse*, mutect2
- SCN4B | c.*2958T>A | 3'UTR (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- SERPINA13P | n.962G>A | RNA (SNP) | VAF 83/391 reads (21%) | catalogued as rs751567044; called by muse, mutect2, varscan2
- SH2D1A | c.*2G>T | 3'UTR (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.8862C>A | RNA (SNP) | VAF 53/185 reads (29%) | catalogued as rs1388684568, COSV100947360; called by muse, mutect2, varscan2
- SYNGR1 | c.338-30C>A | Intron (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- TP53I13 | c.1070-37C>T | Intron (SNP) | VAF 12/136 reads (9%) | catalogued as rs1159991827; called by muse, mutect2
- VIT | c.487+13G>T | Intron (SNP) | VAF 54/373 reads (14%) | catalogued as rs371587076, COSV101007278; called by muse, mutect2, varscan2
- ZNF585B | c.72+7555T>A | Intron (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
